MMRF case MMRF_1760 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d30ea4c0-de06-4121-b070-55787d81b841

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 78.9 years (28,836 days); ISS stage: I; Days to last known disease status: 1,135 days (3.1 years); Days to last follow up: 1,135 days (3.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 134 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 134 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 135 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 211 days; Days to treatment end: 848 days (2.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 211 days; Days to treatment end: 673 days (1.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 953 days (2.6 years); Days to treatment end: 1,113 days (3.0 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 953 days (2.6 years); Days to treatment end: 1,057 days (2.9 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,058 days (2.9 years); Days to treatment end: 1,113 days (3.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 32.3 g/L; Immunoglobulin A 0.642 g/L; Immunoglobulin M 0.458 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 9.5 g/dL; Glucose 5.61 mmol/L.
- Day 78 (ECOG 2): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 27 g/L; Immunoglobulin A 0.609 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 4.5 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 8.5 g/dL; Glucose 5.28 mmol/L.
- Day 169 (ECOG 2): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 25 g/L; Immunoglobulin A 0.396 g/L; Immunoglobulin M 0.363 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 8 g/dL; Glucose 6.77 mmol/L.
- Day 253 (ECOG 2): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 20 g/L; Immunoglobulin A 0.698 g/L; Immunoglobulin M 0.623 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 8.5 g/dL; Glucose 6.05 mmol/L.
- Day 348 (ECOG 2): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 0.723 g/L; Immunoglobulin M 0.524 g/L; Hemoglobin 5.83 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 29 g/L; Total Protein 6.3 g/dL; Glucose 7.21 mmol/L.
- Day 452 (ECOG 2): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 0.926 g/L; Immunoglobulin M 0.662 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 6 mmol/L.
- Day 533 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.629 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 12.1 ×10⁹/L; Absolute Neutrophil 10.5 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 5.34 mmol/L.
- Day 638 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.789 g/L; Immunoglobulin M 0.592 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 7.48 mmol/L.
- Day 708 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 5.67 mmol/L.
- Day 764 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.71 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 7.37 mmol/L.
- Day 848 (ECOG 2): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 8.31 mmol/L.
- Day 988 (ECOG 3): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.96 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 6.6 mmol/L.
- Day 1,086 (ECOG 3): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.82 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 7.1 mmol/L.
- Day 1,135: M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 8.36 mmol/L.

Other clinical attributes
- Day -6: Weight: 68 kg; Height: 178 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1760_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1760_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
